Somatic mutation profile of tumor specimen TARGET-10-PARAFI-09A (aliquot TARGET-10-PARAFI-09A-01D) from TARGET case TARGET-10-PARAFI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,885 days).
Specimen TARGET-10-PARAFI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e51faefc-e8d9-4f42-91b9-4046e21371e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAFI-10A (Blood Derived Normal), aliquot TARGET-10-PARAFI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20ceb8b5-ae4c-4114-9e55-92a783d7020a

The open-access MAF lists 81 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 16, Intron 12, 3'UTR 5, Nonsense Mutation 3, RNA 2, Splice Region 2, 5'UTR 2, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8B | c.1245G>C p.K415N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV64777151; called by muse, mutect2, varscan2
- EFTUD2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV68184914; called by muse, mutect2, varscan2
- ETV6 | c.1058G>C p.R353P | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511694, COSV56766649; called by muse, mutect2, varscan2
- EXOC3L1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as rs1260336885, COSV52045084, COSV52046130; called by muse, mutect2, varscan2
- FBLL1 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs968680154; called by muse, mutect2, varscan2
- FRG1JP | n.596G>T | Splice Region (SNP) | VAF 23/142 reads (16%) | catalogued as rs1298669765; called by muse, mutect2, varscan2
- GJA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs781915687, COSV53788224; called by muse, mutect2, varscan2
- GRM6 | c.1501-8C>T | Splice Region (SNP) | VAF 30/95 reads (32%) | catalogued as rs376899471; called by muse, mutect2, varscan2
- PCDHA5 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV100972409, COSV65353946; called by muse, mutect2, varscan2
- PKD2L1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs193920845, COSV58399502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM9 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 43/180 reads (24%) | catalogued as rs181064967, COSV57008611; called by muse, mutect2, varscan2
- RBBP6 | c.4234G>C p.E1412Q | Missense Mutation (SNP) | VAF 31/381 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100154500; called by muse, mutect2
- SCAF8 | c.1767G>A p.M589I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.177); catalogued as COSV63200206; called by muse, mutect2, varscan2
- SERPINA4 | c.897G>C p.M299I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54070057; called by muse, mutect2, varscan2
- SERPINB12 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs1177966722, COSV54032514; called by muse, mutect2, varscan2
- SLC20A2 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60603332; called by muse, mutect2, varscan2
- TBC1D9B | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs767089909, COSV62281607; called by muse, mutect2, varscan2
- TEK | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs766717660, COSV101193590; called by muse, mutect2, varscan2
- WWC1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575655082, COSV99516265; called by muse, mutect2, varscan2
- ANKRD17 | c.2680C>G p.Q894E | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- BOD1L1 | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- BRCA2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCDC171 | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CENPC | c.218C>G p.S73* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CIBAR2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DAB2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIAPH2 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DMD | c.2505C>A p.F835L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HSP90B1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLHL31 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LDB3 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ME3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MXD1 | c.643C>G p.H215D | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PARP14 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- RAPGEF2 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- RBM23 | c.935C>G p.S312C (on ENST00000359890 / NM_001077351.2; = p.S296C on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RDX | c.1693C>G p.L565V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP1 | c.252_253insGCTCCG p.P84_S85insAP (on ENST00000327443 / NM_138473.3; = p.P77_S78insAP on NM_003109.1) | In Frame Ins (INS) | VAF 30/148 reads (20%) | called by mutect2, pindel, varscan2
- SYNPO2 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TMEM79 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM2 | c.115C>G p.L39V (on ENST00000437508; = p.L66V on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIM38 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 43/151 reads (28%) | called by muse, mutect2, varscan2
- UBAP1 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ABCB7 | c.726G>A p.L242= (on ENST00000373394 / NM_001271696.3; = p.L243= on NM_004299.6) | Silent (SNP) | VAF 126/270 reads (47%) | called by muse, mutect2, varscan2
- CCDC185 | c.1422G>C p.L474= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- CSMD1 | c.1653C>T p.T551= (on ENST00000520002; = p.T550= on NM_033225.6) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1192811052; called by muse, mutect2, varscan2
- FER1L6 | c.3063C>T p.C1021= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs369624500, COSV67548672; called by muse, mutect2, varscan2
- GAREM2 | c.132C>T p.V44= | Silent (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- GPI | c.1275C>T p.L425= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV62894628; called by muse, mutect2, varscan2
- GRM2 | c.1953C>T p.L651= | Silent (SNP) | VAF 53/145 reads (37%) | called by muse, mutect2, varscan2
- HMSD | c.366C>T p.F122= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs772541743, COSV68816777; called by muse, mutect2
- KIF17 | c.831G>A p.L277= | Silent (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- LRRC32 | c.1869G>A p.L623= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs751515768; called by muse, mutect2, varscan2
- MAST1 | c.252G>A p.A84= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs778059086, COSV52246702; called by muse, mutect2, varscan2
- PRPF8 | c.1428C>T p.F476= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- SHANK2 | c.2121G>A p.Q707= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs937992517; called by muse, mutect2, varscan2
- SMAD9 | c.297G>A p.P99= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs559936906, COSV63204822; called by muse, mutect2, varscan2
- TRPM2 | c.1314G>C p.L438= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1488203832, COSV55970273; called by muse, mutect2, varscan2
- ZDHHC12 | c.21C>T p.L7= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1340114387, COSV52576204, COSV52578636; called by muse, mutect2, varscan2
- AHSA1 | c.-1G>A | 5'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- ARF3 | c.*444C>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- CCDC194 | c.421+119A>G | Intron (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- CEP170P1 | n.3556C>T | RNA (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- DDX47 | c.897+148G>A | Intron (SNP) | VAF 12/37 reads (32%) | called by muse, varscan2
- DHX35 | c.*114C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- DMTF1 | chr7:87152430 C>G | 5'Flank (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- DNAH17 | c.11041-325G>C | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- FA2H | c.613+96C>A | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- GRM6 | c.*1209C>G | 3'UTR (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- IDH3G | c.1080+93G>T | Intron (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- MTHFSD | c.443-46G>A | Intron (SNP) | VAF 28/105 reads (27%) | catalogued as rs377719823; called by muse, mutect2, varscan2
- NOL11 | c.1764-108T>C | Intron (SNP) | VAF 5/39 reads (13%) | catalogued as rs576416578; called by muse, mutect2
- PCDH11X | c.3033+3665G>T | Intron (SNP) | VAF 20/136 reads (15%) | catalogued as rs780165314, COSV100015066; called by muse, mutect2, varscan2
- RALGAPA1 | c.2434+1179C>T | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- RHD | c.*172G>C | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- SLC16A7 | c.217+15069C>T | Intron (SNP) | VAF 24/100 reads (24%) | catalogued as rs1031570930; called by muse, mutect2, varscan2
- TBC1D26 | c.199-33G>A | Intron (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- THYN1 | c.-109C>G | 5'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- TTC3P1 | n.4612A>G | RNA (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- TUBA1B | c.*142C>A | 3'UTR (SNP) | VAF 12/37 reads (32%) | catalogued as COSV60136326; called by muse, mutect2, varscan2
- TULP1 | c.1323+73G>C | Intron (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2
